CCDI case PBCJVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/441f3f90-ff68-471c-aa88-403cdf6e7580

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 4.6 years (1,669 days).

Biospecimens (3 samples)
- Sample 0DU7A3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU7A4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU7AA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
